Somatic mutation profile of tumor specimen 0DTC65 from CCDI case PBCJMS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.6 years (1,696 days).
Specimen 0DTC65: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f81f9a7e-4af3-4c4c-afd6-b89dc2db4825.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTC5Y (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2fb59e06-2d00-4014-b646-3a7b1ba187ed

The open-access MAF lists 2 somatic variants for this specimen: 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FIGNL1 | c.417C>T p.I139= | Silent (SNP) | VAF 186/501 reads (37%) | catalogued as rs878934864; called by muse, mutect2, varscan2
- SHOC1 | c.251-399T>C | Intron (SNP) | VAF 132/344 reads (38%) | called by muse, mutect2, varscan2
